CCDI case PBCEET — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/911ef2a9-5c47-4184-9962-41d1495151e9

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Overlapping lesion of brain and central nervous system; Age at diagnosis: 7.2 years (2,648 days).

Biospecimens (3 samples)
- Sample 0DPU2M: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DPU2P: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DPU2Y: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
